Somatic mutation profile of tumor specimen TCGA-D3-A1Q9-06A (aliquot TCGA-D3-A1Q9-06A-11D-A19A-08) from TCGA case TCGA-D3-A1Q9, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 73.2 years (26,746 days).
Specimen TCGA-D3-A1Q9-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c56003d5-a637-42cd-a6c4-ebbf04f477fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A1Q9-10A (Blood Derived Normal), aliquot TCGA-D3-A1Q9-10A-01D-A19A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a281f5b3-d901-440f-b5b4-77650947b1ef

The open-access MAF lists 35 somatic variants for this specimen: 29 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 25, Silent 6, Splice Region 2, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ASPM | c.173G>T p.G58V | Missense Mutation (SNP) | VAF 61/166 reads (37%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV54124697, COSV99660829; called by muse, mutect2, varscan2
- ASPM | c.172G>T p.G58* | Nonsense Mutation (SNP) | VAF 58/163 reads (36%) | catalogued as COSV99660830; called by muse, mutect2, varscan2
- ASXL3 | c.4574C>G p.P1525R | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.868); catalogued as rs894452186, COSV52467216; called by muse, mutect2
- C5orf34 | c.968C>A p.S323Y | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.272); catalogued as COSV100175307, COSV60930256; called by muse, varscan2
- CAVIN1 | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1441613382, COSV63811939; called by muse, mutect2, varscan2
- CEACAM19 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 160/542 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as rs755793782, COSV62551969; called by muse, mutect2, varscan2
- CNTN4 | c.1795C>T p.P599S | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs769761348, COSV61873426; called by muse, mutect2, varscan2
- DRD5 | c.1276G>C p.D426H | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.436); catalogued as rs1187122781, COSV58578358; called by muse, mutect2, varscan2
- FAT1 | c.10499C>T p.S3500L | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as COSV101499482, COSV71674329; called by muse, mutect2
- FRMD4B | c.2985A>G p.R995= | Splice Region (SNP) | VAF 72/137 reads (53%) | catalogued as COSV68330245; called by muse, mutect2, varscan2
- HERC2 | c.4002C>T p.A1334= | Splice Region (SNP) | VAF 16/36 reads (44%) | catalogued as COSV55319148; called by muse, mutect2, varscan2
- HNRNPH1 | c.41A>C p.K14T | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61486043; called by muse, mutect2, varscan2
- IL7R | c.814G>A p.V272I | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs369971728, COSV57406004; called by muse, mutect2, varscan2
- ITGAD | c.2015T>C p.V672A | Missense Mutation (SNP) | VAF 108/209 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV66758238; called by muse, mutect2, varscan2
- ITGAV | c.957T>G p.D319E | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as COSV53713012; called by muse, varscan2
- KCNB2 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as rs756745272, COSV73049820; called by muse, mutect2, varscan2
- MIB1 | c.2963G>C p.R988P | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV55090997; called by muse, mutect2, varscan2
- NUP88 | c.2110A>T p.I704F | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.747); catalogued as COSV52585160; called by muse, mutect2, varscan2
- PARP4 | c.9G>T p.M3I | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as COSV67962014; called by muse, mutect2, varscan2
- PC | c.3364G>C p.D1122H | Missense Mutation (SNP) | VAF 191/270 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs745961257, COSV58992822; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PKHD1L1 | c.2935A>G p.T979A | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.114); catalogued as rs1225804147, COSV65743745; called by muse, mutect2, varscan2
- PTPN22 | c.1651C>T p.L551F (on ENST00000359785 / NM_001193431.2; = p.L496F on NM_012411.5) | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.106); catalogued as rs1366562478, COSV63085225; called by muse, mutect2, varscan2
- SLC44A1 | c.677C>G p.S226C | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV58264633; called by muse, mutect2, varscan2
- ST8SIA5 | c.129G>C p.K43N | Missense Mutation (SNP) | VAF 13/36 reads (36%) | PolyPhen benign (0.117); catalogued as COSV100164841; called by muse, mutect2, varscan2
- TEX15 | c.2978T>C p.L993P (on ENST00000256246; = p.L1376P on NM_001350162.2) | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV56347087; called by muse, mutect2, varscan2
- WASHC4 | c.830C>A p.S277Y | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.195); catalogued as COSV59889894; called by muse, mutect2, varscan2
- POGZ | c.2049_2052dup p.G685Tfs*22 | Frame Shift Ins (INS) | VAF 135/344 reads (39%) | called by mutect2, pindel, varscan2
- SMTNL1 | c.182G>A p.G61D | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.356); called by muse, mutect2
- ARHGAP36 | c.696G>A p.A232= | Silent (SNP) | VAF 25/33 reads (76%) | catalogued as COSV52267284; called by muse, mutect2, varscan2
- COX7A2 | c.195A>G p.K65= | Silent (SNP) | VAF 6/111 reads (5%) | catalogued as COSV57873967; called by muse, mutect2
- FPR3 | c.144C>A p.I48= | Silent (SNP) | VAF 30/89 reads (34%) | catalogued as COSV59330066; called by muse, mutect2, varscan2
- PLCB1 | c.990G>A p.S330= | Silent (SNP) | VAF 56/127 reads (44%) | catalogued as rs375950955; ClinVar: likely benign; called by muse, mutect2, varscan2
- RPS16 | c.345T>C p.Y115= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as COSV52239223, COSV99261740; called by muse, mutect2, varscan2
- TDRD1 | c.2622C>T p.T874= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs748452799, COSV52590148, COSV52591211; called by muse, mutect2, varscan2
